Somatic mutation profile of tumor specimen MP2PRT-PARMGD-TMP1-A (aliquot MP2PRT-PARMGD-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARMGD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,497 days).
Specimen MP2PRT-PARMGD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9cf58a2-eeac-46d0-9dda-3cede31b69f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMGD-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMGD-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6f2d6ca-c85e-4cd0-918a-d1ccdc744771

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL18A1 | c.3683G>A p.R1228H (on ENST00000359759 / NM_130444.3; = p.R993H on NM_030582.4) | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1322668436; called by muse, varscan2
- CTCF | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 143/346 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104382064; called by muse, mutect2, varscan2
- CYP27A1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 134/383 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs760323157, CM164521, COSV51468724; called by muse, mutect2, varscan2
- GSTM2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 85/461 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PRR36 | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 207/918 reads (23%) | SIFT tolerated (0.43); called by muse, varscan2
- SEPTIN11 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 48/654 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.125); called by muse, mutect2
- TACR3 | c.339C>A p.H113Q | Missense Mutation (SNP) | VAF 189/770 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- UNC80 | c.3855C>T p.G1285= | Silent (SNP) | VAF 106/242 reads (44%) | catalogued as rs917171654; called by muse, varscan2
